Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5722, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5722-01A (Primary Tumor).

*** Diagnosis(es): ***

1.: Obviously localized, highly differentiated papillary serous tumor of the peritoneum. No metastases from the carcinoma described below.

2.: Total gastrectomy specimen including an ulcerated, weakly differentiated adenocarcinoma (intestinal type) of maximum diameter 5 cm located in the corpus region with wide infiltration of the perigastric fatty tissue and localized penetration of the covering serosa and with about 14 regional lymph node metastases, in some cases invading the capsule and merging to form a conglomerate.

Tumor-free oral resection margin lined with regular squamous epithelium. Tumor-free duodenal resection margin with evidence of heterotopic gastric corpus mucosa. Tumor-free omental fatty tissue.

3.: Lymph node metastasis from the above carcinoma (clinically trunk).

Tumor stage (taking into account the preliminary findings with admission number

pT3 pN2 (15/21) pM

Source: NCI Genomic Data Commons file b2566cc0-a88e-4953-b100-7ed05edd8b9c (TCGA-CG-5722.774EE209-8C41-4F81-9312-07A0FF92C26C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).